CCDI case PBCJYN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6791602b-8f0b-494a-91d0-9aff6b1ff80d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 10.3 years (3,774 days).

Biospecimens (3 samples)
- Sample 0DU07E: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU07M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU07R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
